Somatic mutation profile of tumor specimen 0DX0R0 from CCDI case PBCPKZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.4 years (4,542 days).
Specimen 0DX0R0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ba43a98-90f5-4f58-9a7a-1216c93ae7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/381ca71b-aab5-4873-a1b1-6d803e797227

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Intron 3, 3'UTR 2, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS2 | c.467dup p.L156Ffs*11 | Frame Shift Ins (INS) | VAF 98/910 reads (11%) | catalogued as rs528833893; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- C22orf39 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 23/742 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1302087910, COSV100287038; called by muse, mutect2
- CREBBP | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99268435; called by muse, mutect2
- OR8K3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 35/1218 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200418517, COSV57130852; called by muse, mutect2
- S1PR2 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 78/367 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528470769; called by muse, mutect2, varscan2
- SPANXN2 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 63/772 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs782627806; called by muse, varscan2
- TET2 | c.3446C>T p.T1149I | Missense Mutation (SNP) | VAF 289/740 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1278154244; called by muse, mutect2, varscan2
- TMEM221 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 50/415 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs750708186; called by muse, mutect2, varscan2
- TSC2 | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766093661, COSV51919310; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WDR37 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1433377878, COSV54129917; called by muse, mutect2
- WHRN | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 269/615 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753379063; called by muse, mutect2, varscan2
- COL2A1 | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 60/688 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH2 | c.5960C>A p.A1987D | Missense Mutation (SNP) | VAF 49/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INSM1 | c.130_143del p.P44Gfs*290 | Frame Shift Del (DEL) | VAF 105/201 reads (52%) | called by mutect2, varscan2
- KMT2D | c.8720dup p.Y2907* | Nonsense Mutation (INS) | VAF 49/265 reads (18%) | called by mutect2, pindel, varscan2
- OR1L6 | c.964C>A p.L322M (on ENST00000373684; = p.L286M on NM_001004453.2) | Missense Mutation (SNP) | VAF 370/834 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by mutect2, varscan2
- OR2M5 | c.568A>C p.N190H | Missense Mutation (SNP) | VAF 37/1411 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2
- PCDHA12 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 213/1007 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPEN | c.9743C>T p.A3248V | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.051); called by muse, mutect2
- TRIM33 | c.3071_3072del p.F1024Cfs*12 | Frame Shift Del (DEL) | VAF 432/1192 reads (36%) | called by mutect2, pindel, varscan2
- UBE3B | c.3190G>A p.G1064S | Missense Mutation (SNP) | VAF 27/582 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC45A | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 273/615 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- Z83844.2 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 51/699 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2
- C4orf46 | c.267A>C p.T89= | Silent (SNP) | VAF 217/1264 reads (17%) | called by muse, mutect2, varscan2
- NBR1 | c.2205C>A p.I735= | Silent (SNP) | VAF 46/828 reads (6%) | called by muse, mutect2
- POTEE | c.1080C>T p.Y360= | Silent (SNP) | VAF 231/772 reads (30%) | catalogued as rs553100151; called by muse, mutect2, varscan2
- VWA5B1 | c.1563G>T p.L521= | Silent (SNP) | VAF 391/775 reads (50%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/482 reads (3%) | called by muse, mutect2
- DHRS3 | c.*32G>A | 3'UTR (SNP) | VAF 201/425 reads (47%) | catalogued as rs763998461; called by muse, mutect2, varscan2
- ITIH4 | c.1171+76G>T | Intron (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- SGK1 | c.883-33A>G | Intron (SNP) | VAF 77/420 reads (18%) | called by muse, mutect2, varscan2
- UNK | c.*85A>G | 3'UTR (SNP) | VAF 46/246 reads (19%) | catalogued as rs1020761702, COSV52886076; called by muse, varscan2
